Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8C8, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8C8-01A (Primary Tumor).

[page 1 of 5]
Surg Path Final Report

Temporary Copy

Page 1 of 2

Case

Collected

Ordered by

ACCESSION

Submitting Physician

Clinical History

Low-grade glioma

Diagnosis

1. BRAIN TUMOR, UNSPECIFIED SITE, RESECTION:
- OLIGODENDROGLIOMA, WHO GRADE II
2. BRAIN TUMOR, UNSPECIFIED SITE, RESECTION:
- OLIGODENDROGLIOMA, WHO GRADE II

ICD-O-3

Oligodendroglioma, grade II
9450/3

Site
CCF: Brain, supratentorial NOS
C71.0

path: Cerebrum C71.0
QW11/27/13

I certify that I personally conducted the
diagnostic evaluation on the above specimens
and have rendered the above diagnosis(es):

electronic signature

For questions regarding this case, call

Frozen Section Diagnosis

Frozen section diagnosis per

1FA: "Low-grade glioma"

Gross Description

Two specimens are received labeled with the patient's name and medical record number.

Specimen one is received fresh for frozen section labeled "tumor", and consists of an aggregate of pink-tan soft tissue fragments measuring 1.3 x 1.0 x 0.2 cm. A representative section is submitted for frozen section. After frozen section the specimen is wrapped, transferred and submitted in cassette 1FA for permanents. The remainder of the specimen is submitted in cassette 1A.

Specimen two is received in formalin labeled "tumor", and consists of an aggregate of pink-tan, irregular soft tissue fragments measuring 2.2 x 1.2 x 0.5 cm. Submitted entirely in cassette 2A.

Microscopic Examination

Performed.

The frozen section diagnosis is confirmed on permanent sections.

Synoptic Report

College of American Pathologists (CAP) Cancer Protocol

[page 2 of 5]
Surg Path Final Report

Temporary Copy

Page 2 of 2

Case

Collector

Ordering

Patient

Location

Surgical Pathology Cancer Case Summary (Checklist)

Protocol effective date:

History of Previous Tumor/ Familial Syndrome
Not specified

Specimen Type/Procedure
Resection

Specimen Handling
Squash/smear/touch preparation
Frozen section
Unfrozen for routine permanent paraffin sections

Specimen Size
Greatest dimension: 2.2 cm

Laterality
Not specified

Tumor Site
Brain/cerebrum

Histologic Type and Grade (applicable World Health
Organization [WHO] classification and grade)
Oligodendroglioma (WHO grade II)

Histologic Grade (WHO histologic grade)
WHO grade II

Ancillary Studies

Immunohistochemistry:
MIB-1 - fields with up to 10% proliferation index

Molecular genetic studies:
1p FISH - pending
19q FISH - pending

Additional Pathological Findings
None

[page 3 of 5]
Addendum Report
Temporary Copy

Page 1 of 1

Case:

Collection:

Ordered by:

Location:

ACCESSION

Addendum Discussion

Fluorescence in-situ hybridization (FISH) analysis for deletions of 1p and/or 19q are performed on sections from block "2A".

Calculated 1p/1q ratio = 0.98 (<0.74 is deleted)

Calculated 19q/19p ratio = 0.90 (<0.88 is deleted)

The results are interpreted as not deleted for both 1p and 19q.

A result of a deleted 1p and 19q suggests a favorable prognosis. A solitary 1p deletion suggests an intermediate prognosis. A 19q solitary deletion may suggest a favorable prognosis in a smaller subset of tumors. The lack of either 1p and/or 19q deletion(s) is considered a poor prognostic indicator and may be associated with decreased disease-free survival and overall survival.

There is no change to the original diagnosis.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

[page 4 of 5]
Addendum Report

Temporary Copy

Page 1 of 1

Case

Collected

Order by

ACCESSION

Addendum Discussion

At the request of the clinicians, immunohistochemistry for IDH-1 was performed on this tumor. The tumor is diffusely positive for IDH-1, making it likely that the tumor is mutated for IDH-1. The diagnosis is unchanged.

This test was developed and its performance characteristics determined by

The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use. The results are not intended **to be used as the sole means** for clinical diagnosis or patient management decisions.

I certify that I personally conducted the diagnostic evaluation on the above specimen(s) and have rendered the above diagnosis(es):

electronic signature

[page 5 of 5]
Addendum Report
Temporary Copy

Page 1 of 1

Case:

Collected:

Ordered by:

Location:

ACCESSION

Addendum Discussion

MGMT METHYLATION ASSAY : GENE METHYLATION DETECTED.

MGMT Methylation Assay was performed on sections from block "2A" by . The results of this assay are reported below:

MGMT Methylation Assay:

Result: Gene Methylation detected.
Methylation Score: 27.13

--REFERENCE VALUE--
unmethylated <2.00
methylated >=2.00

Background:

MGMT [O(6)-methylguanine-DNA methyltransferase] is a DNA repair enzyme that is involved in the repair of damage caused by a variety of DNA crosslinking compounds, including alkylating agents. Increased methylation of the MGMT gene promotor region causes diminished or silenced expression of the gene, making cells more sensitive to DNA damage. This relationship has been shown for glioblastomas and alkylating agents such as temozolomide. Approximately 40-50% of glioblastomas exhibit MGMT gene methylation. Retrospective studies have shown that detection of MGMT promotor methylation in tumor samples is associated with an increased likelihood of a favorable response to temozolomide.

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimens. Molecular analysis of the MGMT gene is performed by methylation-specific PCR and detected on . The MGMT and beta-Actin copy numbers are used to calculate the ratio of MGMT/beta-Actin x 1000. Molecular-based testing is highly accurate, but as in any laboratory test, rare diagnostic errors may occur. Results of this test are for Investigational Purposes Only. The performance characteristics of this assay have been determined by . The result should not be used as a diagnostic procedure without confirmation of the diagnosis by another medically established diagnostic product or procedure.

I certify that I personally conducted the diagnostic evaluation on the above specimen(s) and have rendered the above diagnosis(es):

electronic signature

HPA Discrepancy		☒
Qual/Sync/Chronous Primary/Not		

Source: NCI Genomic Data Commons file b708df96-59fb-4925-b400-b1ca7aace5e4 (TCGA-VM-A8C8.11BD5D8D-FB5B-4D96-A421-EC8524E8AA6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).